Surgical pathology report (de-identified scan), TCGA case TCGA-AG-3999, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AG-3999-01A (Primary Tumor).

Diagnosis:

Resected sample of colon (rectosigmoid) with tumor-free oral, aboral and perirectal resection margins and including an ulcerated, moderately differentiated (G2) adenocarcinoma with infiltration of the perimuscular fatty tissue. Numerous local lymph node metastases (pT3, L1, v1 local R0 pN2 20/32).

Source: NCI Genomic Data Commons file 6545e41f-8ae5-4958-b047-ecd3ecbbcc20 (TCGA-AG-3999.992909EE-14DF-4602-9961-57C96F253582.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).